Surgical pathology report (de-identified scan), TCGA case TCGA-56-8082, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-8082-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

* Final Report *

Result type:
Result date:
Result status:
Result title:
Performed by:
Verified by:
Encounter info:

* Final Report *

Clinical History

Right lung mass

Specimen

- #1 Level 11
- #2 Right lower lobe (tissue study)
- #3 Level 10 lymph nodes
- #4 Level 8 lymph nodes
- #5 Level 4R

Gross Examination

#1 Received in formalin labeled level 11 is one piece of soft, black/tan tissue measuring 0.6 x 0.4 x 0.3 cm. Entirely submitted in one cassette.

#2 Received fresh labeled right lower lobe, is one lobectomy specimen measuring 13.0 x 10.0 x 3.0 cm and weighing 200 grams. The bronchial margin is shaved and submitted for Frozen Section. Abutting the pleural surface there is a firm, fleshy mass measuring 5.5 x 4.5 x 3.0 cm, approaching within 3.0 cm of the bronchial margin. The mass puckers the overlying pleura but does not appear to invade through it. The remainder of the lung parenchyma is unremarkable. Representative sections are submitted per the block summary. Block summary: "A", vessel margins; "B", mass with overlying pleura; "C,D", mass and adjacent normal; "E", uninvolved parenchyma, per patient consent tissue was submitted for tissue study as well.

#3 Received in formalin labeled level 10 lymph node is one piece of soft tan/black tissue measuring 0.8 x 0.5 x 0.3 cm. Entirely submitted in one cassette.

#4 Received in formalin labeled level 8 lymph node is one piece of soft, pink-tan tissue measuring 1.0 x 0.6 x 0.3 cm. Entirely submitted in one

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 2 of 3]
Surgical Pathology Report

* Final Report *

cassette.

#5 Received in formalin labeled level 4R is one piece of firm, tan tissue measuring 2.1 x 0.5 x 0.5 cm. The specimen is bisected in the long axis and entirely submitted in one cassette.

Frozen Section Diagnosis

#2 RIGHT LOWER LOBE, LOBECTOMY (1 FS): BRONCHIAL MARGIN, NEGATIVE FOR CARCINOMA. REPORTED TO

Microscopic Examination

#1-5 Microscopic examination performed.

Final Diagnosis

#1 MEDIASTINAL LYMPH NODE, LEVEL 11, EXCISION: ONE BENIGN LYMPH NODE (0/1).

#2 LUNG, RIGHT LOWER LOBE, LOBECTOMY: SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED.

TUMOR SIZE: 5.5 X 4.5 X 3.0 CM.

PROXIMAL BRONCHIAL RESECTION MARGIN STATUS: NEGATIVE FOR CARCINOMA.

PLEURAL SURFACE STATUS: NEGATIVE FOR CARCINOMA.

DIRECT EXTENSION TO TUMOR: NOT IDENTIFIED.

LYMPHOVASCULAR SPACE STATUS: NO LYMPHOVASCULAR SPACE INVASION IDENTIFIED.

PATHOLOGIC STAGE (TNM CLASSIFICATION): pT2b pN0.

#3 MEDIASTINAL LYMPH NODE, LEVEL 10, EXCISION: ONE BENIGN LYMPH NODE (0/1).

#4 MEDIASTINAL LYMPH NODE, LEVEL 8, EXCISION: ONE BENIGN LYMPH NODE (0/1).

#5 MEDIASTINAL LYMPH NODE, LEVEL 4R, EXCISION: ONE BENIGN LYMPH NODE (0/1).

Signature Line

Signed by:
ELECTRONIC SIGNATURE

Ordering Provider

Ordering Physician:

Printed by:
Printed on:

Page 2 of 3
(Continued)

[page 3 of 3]
Surgical Pathology Report

* Final Report *

Printed by:
Printed on:

Page 3 of 3
(End of Report)

Source: NCI Genomic Data Commons file b2b2faee-6fcd-478c-9667-2c8f6925eb6f (TCGA-56-8082.0DBA1129-8D66-465D-9AB7-6B42515442F0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).